Somatic mutation profile of tumor specimen TCGA-B0-5083-01A (aliquot TCGA-B0-5083-01A-02D-1421-08) from TCGA case TCGA-B0-5083, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 63.1 years (23,034 days).
Specimen TCGA-B0-5083-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea1bc9f8-8f50-427b-8522-77cd1c192b49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5083-11A (Solid Tissue Normal), aliquot TCGA-B0-5083-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/667b0de2-c3dd-4cfc-87ea-fec221619909

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.8518C>A p.P2840T | Missense Mutation (SNP) | VAF 22/375 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.124); catalogued as COSV52164735; called by muse, mutect2
- CCDC181 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63155619, COSV63156673; called by muse, mutect2
- CNR2 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV65693119; called by muse, mutect2, varscan2
- DTX4 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1423783336, COSV57091470, COSV57092379; called by muse, mutect2
- MUC4 | c.2347G>A p.G783R | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.955); catalogued as rs757054538, COSV62154565; called by muse, mutect2, varscan2
- PCDHGB4 | c.2293C>G p.L765V | Missense Mutation (SNP) | VAF 225/559 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV53961891; called by muse, mutect2, varscan2
- RB1CC1 | c.4443G>T p.M1481I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.933); catalogued as rs1215904517, COSV99206107; called by mutect2, varscan2
- RFX6 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 12/97 reads (12%) | catalogued as COSV60585858; called by muse, mutect2, varscan2
- SEL1L3 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV53542263; called by muse, mutect2
- TGM1 | c.1369del p.V457Wfs*31 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as COSV99253313; called by mutect2, pindel, varscan2
- TRIM23 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as COSV51551797; called by muse, mutect2
- TRIM6 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53476670; called by muse, mutect2
- VSIR | c.926A>G p.E309G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV56468441; called by muse, mutect2
- IRX5 | c.645C>T p.G215= | Silent (SNP) | VAF 8/225 reads (4%) | catalogued as COSV58058739; called by muse, mutect2
- PTPN23 | c.3522G>A p.L1174= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV55545210; called by muse, mutect2, varscan2
- SPAG17 | c.1914C>T p.N638= | Silent (SNP) | VAF 13/278 reads (5%) | catalogued as COSV60460427; called by muse, mutect2
